Somatic mutation profile of tumor specimen TCGA-4C-A93U-01A (aliquot TCGA-4C-A93U-01A-11D-A397-08) from TCGA case TCGA-4C-A93U, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 74.9 years (27,348 days).
Specimen TCGA-4C-A93U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f1415a1-ad35-437b-81b0-56ea50126323.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4C-A93U-10A (Blood Derived Normal), aliquot TCGA-4C-A93U-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e4a76db-064f-46ec-b15d-420aa3484bbb

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 15, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TWNK | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs556445621, CM1411682, COSV99272667; ClinVar: likely benign / pathogenic; called by muse, mutect2, varscan2
- ALDH2 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs571588910, COSV55667203; called by muse, mutect2, varscan2
- ALKBH6 | c.193C>T p.P65S (on ENST00000252984 / NM_001297701.2; = p.P93S on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99431154; called by muse, mutect2, varscan2
- ANKRD26 | c.414T>A p.D138E | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV101066504; called by muse, mutect2, varscan2
- ANPEP | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100263191; called by muse, mutect2, varscan2
- ATP8B3 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.239); catalogued as COSV99402426; called by muse, mutect2, varscan2
- CNNM1 | c.1569G>C p.K523N | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100763901; called by muse, mutect2, varscan2
- CNTNAP5 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101443718; called by muse, mutect2, varscan2
- CRYBG1 | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.233); catalogued as COSV100954536; called by muse, mutect2, varscan2
- EIF3F | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.556); catalogued as rs1167004834, COSV100562587; called by muse, mutect2, varscan2
- EXOSC10 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100442639; called by muse, mutect2, varscan2
- FGD5 | c.2086G>C p.D696H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV53253760, COSV99548391; called by muse, mutect2, varscan2
- GDI2 | c.85A>G p.K29E | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV101200790; called by muse, mutect2, varscan2
- H1-10 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100412952; called by muse, mutect2
- H3C10 | c.241A>G p.T81A | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV100297627; called by muse, mutect2, varscan2
- HTRA2 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV51208092; called by muse, mutect2, varscan2
- KANSL2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.208); catalogued as COSV100770989; called by muse, mutect2, varscan2
- KAT6B | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1362389122, COSV99767280; called by muse, mutect2, varscan2
- KIAA1549L | c.3800G>C p.R1267T (on ENST00000321505; = p.R1564T on NM_012194.3) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99683763; called by muse, mutect2, varscan2
- LLGL1 | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100375381, COSV57499651; called by muse, mutect2, varscan2
- MAP3K1 | c.3146C>G p.S1049* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV68126827; called by muse, mutect2, varscan2
- MEOX2 | c.313C>G p.R105G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.972); catalogued as rs373584566; called by muse, varscan2
- PLCL1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs201197388; called by muse, mutect2, varscan2
- RANBP3L | c.1112T>A p.V371E | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV99683884; called by muse, mutect2, varscan2
- RBM22 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99556038; called by muse, mutect2, varscan2
- RCAN1 | c.380A>G p.H127R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100571681; called by muse, mutect2, varscan2
- RICTOR | c.4897G>A p.E1633K | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57118660, COSV57132441, COSV99705219; called by muse, mutect2, varscan2
- STOX2 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100408847; called by muse, mutect2, varscan2
- STXBP3 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1275580648, COSV100894019; called by muse, mutect2, varscan2
- TNPO2 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV63507465, COSV63507622; called by muse, mutect2, varscan2
- TTC36 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as rs377476216; called by muse, mutect2, varscan2
- VPS13B | c.4618A>T p.T1540S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.14); catalogued as COSV100662382; called by muse, mutect2, varscan2
- ZNF106 | c.2879G>C p.R960T | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs1168485152, COSV99782745; called by muse, mutect2, varscan2
- ZNF687 | c.3480G>C p.K1160N | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV99649870; called by muse, mutect2, varscan2
- ZNF711 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99340681; called by muse, mutect2, varscan2
- ARID2 | c.688_697del p.D230Sfs*59 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- CCDC110 | c.2478dup p.D827Rfs*25 | Frame Shift Ins (INS) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- MDC1 | c.5508_5509del p.V1837Dfs*50 | Frame Shift Del (DEL) | VAF 51/157 reads (32%) | called by mutect2, pindel, varscan2
- ABCC12 | c.3240G>A p.T1080= | Silent (SNP) | VAF 81/221 reads (37%) | catalogued as COSV60911255; called by muse, mutect2, varscan2
- DNAJC13 | c.5343C>T p.L1781= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99607519; called by muse, mutect2, varscan2
- DNAJC3 | c.1317C>T p.F439= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs1273669855, COSV100953400; called by muse, mutect2, varscan2
- ECHS1 | c.627C>G p.V209= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100881913; called by muse, mutect2, varscan2
- ESF1 | c.1173G>A p.K391= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99176403; called by muse, mutect2, varscan2
- HERC1 | c.14001C>T p.I4667= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs760023312, COSV71246458; called by muse, mutect2, varscan2
- INCENP | c.69C>T p.L23= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99611187; called by muse, mutect2, varscan2
- MYT1 | c.1155C>T p.I385= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs780815194, COSV60513062; called by muse, mutect2, varscan2
- NDUFS2 | c.1272C>T p.I424= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as COSV99248326; called by muse, mutect2, varscan2
- PHACTR3 | c.996C>T p.S332= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs760921402, COSV63031467; called by muse, mutect2, varscan2
- PLEKHH3 | c.1530C>T p.H510= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs753578155, COSV52218075, COSV99257684; called by muse, mutect2, varscan2
- PXDNL | c.4182G>A p.G1394= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as COSV100684440; called by muse, mutect2, varscan2
- SPART | c.1002G>A p.R334= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100768786; called by muse, mutect2, varscan2
- TBR1 | c.858C>G p.V286= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV101271488; called by muse, mutect2, varscan2
- THSD7A | c.3519A>T p.P1173= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101439762; called by muse, mutect2
- C2orf15 | c.-11C>G | 5'UTR (SNP) | VAF 29/91 reads (32%) | catalogued as COSV100209010; called by muse, mutect2, varscan2
